Gene-level copy-number profile of tumor specimen MP2PRT-PASPCZ-TMP1-A from MP2PRT case MP2PRT-PASPCZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,131 days).
Specimen MP2PRT-PASPCZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a90df328-71a9-43ef-b5e9-690744e95744.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASPCZ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/dc05e2c6-76c4-48d5-b9b5-1d55cd728f49

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 466; copy number 1: 4,564; copy number 2: 53,335; copy number 3: 390; copy number 4: 135.

Homozygous deletions (total copy number 0; autosomes only): 466 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,254,015, 43 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:89,959,979–90,053,372, 11 genes: IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18.
- chr2:90,220,727–90,315,836, 4 genes: IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118.
- chr2:91,617,160–92,035,000, 18 genes (within-gene range 0–2): LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P, IGKV1OR2-1, ABCD1P5, AC127391.1, PABPC1P6, SLC9B1P2, ACTR3BP2, CHEK2P3, AC128677.1, IGKV1OR2-2.
- chr2:113,325,372–113,425,548, 1 gene (within-gene range 0–2): AC016745.1.
- chr2:113,432,600–113,436,042, 1 gene: AC016745.2.
- chr3:127,221,194–127,288,046, 3 genes: AC112482.1, RNU6-1047P, PRR20G.
- chr6:170,615,515–170,738,536, 1 gene (within-gene range 0–1): AL672310.1.
- chr6:170,736,173–170,737,777, 1 gene: AL731684.1.
- chr9:36,833,269–37,034,268, 5 genes (within-gene range 0–2): PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2.
- chr14:21,950,406–22,552,156, 109 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,631,653, 134 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,637,718–106,639,657, 2 genes (within-gene range 0–2): IGHVII-60-1, IGHV4-61.
- chr14:106,657,725–106,704,286, 11 genes (within-gene range 0–2): IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68.
- chr15:75,843,307–75,942,511, 3 genes (within-gene range 0–2): UBE2Q2, RN7SL510P, FBXO22.
- chr22:22,030,934–22,896,111, 119 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,708. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
